Somatic mutation profile of tumor specimen TCGA-DM-A28F-01A (aliquot TCGA-DM-A28F-01A-11D-A16V-10) from TCGA case TCGA-DM-A28F, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.5 years (26,856 days).
Specimen TCGA-DM-A28F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a226e4a3-7a22-4f9e-9060-7fe2f542aa8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A28F-10A (Blood Derived Normal), aliquot TCGA-DM-A28F-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ada52ea-65b1-4975-8735-eb0516932e5d

The open-access MAF lists 260 somatic variants for this specimen: 193 protein-altering or splice-affecting, 62 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 62, Nonsense Mutation 13, Frame Shift Ins 6, Splice Site 5, Frame Shift Del 5, RNA 3, Splice Region 2, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- B2M | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | hotspot (GDC flag); catalogued as rs111947448, COSV62563163, COSV62563826; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 35/54 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs201134913, CM140756; called by muse, mutect2, varscan2
- ABCA13 | c.2820A>C p.E940D | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.93); catalogued as COSV70025519, COSV70028233; called by muse, mutect2, varscan2
- ABLIM3 | c.1921G>T p.D641Y | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58644346; called by muse, mutect2, varscan2
- ACRBP | c.208A>G p.N70D | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.207); catalogued as COSV57524209; called by muse, mutect2, varscan2
- ADAMTS19 | c.2621A>C p.K874T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV50754601; called by muse, mutect2
- ALPL | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs552831415, CM045925, COSV66376308; called by muse, mutect2, varscan2
- ANKRD30A | c.1515A>C p.K505N (on ENST00000611781; = p.K449N on NM_052997.2) | Missense Mutation (SNP) | VAF 130/349 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as COSV64612384; called by muse, mutect2, varscan2
- ARHGAP31 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51794180; called by muse, mutect2, varscan2
- ARHGAP39 | c.2551T>G p.C851G (on ENST00000276826 / NM_001308208.2; = p.C882G on NM_025251.2) | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52771323; called by muse, mutect2, varscan2
- ARHGEF6 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1288145761, COSV51688290; called by muse, mutect2, varscan2
- ATP10A | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746447082, COSV63518559; called by muse, mutect2, varscan2
- ATP8B2 | c.1185G>C p.K395N (on ENST00000672630; = p.K362N on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV59246486; called by muse, mutect2, varscan2
- BANP | c.1097C>T p.P366L (on ENST00000286122; = p.P335L on NM_017869.4) | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.241); catalogued as rs1312556213, COSV53738732; called by muse, mutect2, varscan2
- BAZ1A | c.3764A>T p.E1255V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV62410529; called by muse, mutect2, varscan2
- BAZ1A | c.3763G>T p.E1255* | Nonsense Mutation (SNP) | VAF 44/167 reads (26%) | catalogued as COSV62410532; called by muse, mutect2, varscan2
- BICDL1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs761777351, COSV99984578; called by mutect2, varscan2
- BNC2 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV101033030, COSV101033325; called by muse, mutect2, varscan2
- C1D | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV63413458; called by muse, mutect2, varscan2
- CACNA1E | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62399794; called by muse, mutect2, varscan2
- CARD6 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV54566739; called by muse, mutect2, varscan2
- CARD9 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1326775525, COSV100047145; called by muse, varscan2
- CASP8 | c.1124C>T p.S375L (on ENST00000432109 / NM_033355.3; = p.S392L on NM_001228.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV51851118, COSV51852448; called by muse, mutect2, varscan2
- CCDC40 | c.2740_2741insC p.I914Tfs*84 | Frame Shift Ins (INS) | VAF 41/152 reads (27%) | catalogued as COSV66475630, COSV66476240; called by mutect2, pindel, varscan2
- CDC37 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99705769; called by muse, mutect2, varscan2
- CDH4 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64658072; called by muse, mutect2, varscan2
- CDK6 | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.161); catalogued as COSV99721133; called by muse, mutect2, varscan2
- CFAP20DC | c.1333G>A p.D445N (on ENST00000482387 / NM_001351530.2; = p.D320N on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV55921460; called by muse, mutect2, varscan2
- CFAP69 | c.1864C>G p.Q622E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100290044; called by muse, mutect2
- CFHR4 | c.127_128insA p.F43Yfs*14 (on ENST00000367416 / NM_001201551.2; = p.F44Yfs*14 on NM_006684.5) | Frame Shift Ins (INS) | VAF 47/190 reads (25%) | catalogued as COSV52230266; called by mutect2, pindel, varscan2
- CHRDL1 | c.1160A>C p.K387T (on ENST00000372045; = p.K393T on NM_145234.4) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV54323890, COSV99488033; called by muse, mutect2
- CLASP2 | c.2241G>A p.V747= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100223308; called by muse, mutect2, varscan2
- CLSTN2 | c.2387C>G p.S796* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV71721381; called by muse, mutect2, varscan2
- CNNM2 | c.893A>T p.E298V | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63996011; called by muse, mutect2, varscan2
- COL4A2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1324354794, COSV64629266; called by muse, mutect2, varscan2
- COL6A3 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs780353083, COSV55092996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ2 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV61021714; called by muse, mutect2, varscan2
- CUL3 | c.2068G>T p.E690* | Nonsense Mutation (SNP) | VAF 89/303 reads (29%) | catalogued as COSV52365611; called by muse, mutect2, varscan2
- CYB5R3 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV61545756; called by muse, mutect2, varscan2
- DAGLA | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 140/246 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57196912; called by muse, mutect2, varscan2
- DNAH1 | c.4897G>A p.D1633N | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745913547, COSV70229999; called by muse, mutect2, varscan2
- DNAH5 | c.5549A>C p.K1850T | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs777809376, COSV54237188; called by muse, mutect2, varscan2
- DOT1L | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs200802307; called by muse, mutect2, varscan2
- DPY19L1 | c.900G>C p.L300F | Missense Mutation (SNP) | VAF 299/603 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV60582716; called by muse, mutect2, varscan2
- DSCAM | c.4661C>T p.A1554V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474691893, COSV68028533; called by muse, mutect2, varscan2
- DST | c.17569C>G p.P5857A (on ENST00000361203 / NM_001374722.1; = p.P3554A on NM_015548.5) | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.966); catalogued as COSV55019538; called by muse, mutect2, varscan2
- EEF2 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV58579758; called by muse, mutect2, varscan2
- EHMT1 | c.2195C>A p.P732H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100603734, COSV58380341; called by muse, mutect2
- ERMP1 | c.2387G>A p.G796E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53037789; called by muse, mutect2, varscan2
- ERMP1 | c.2387-1G>A p.X796_splice | Splice Site (SNP) | VAF 11/63 reads (17%) | catalogued as COSV53037798; called by muse, mutect2, varscan2
- ESYT2 | c.1314G>C p.W438C (on ENST00000613624; = p.W362C on NM_020728.3) | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51752097; called by muse, mutect2, varscan2
- FAF2 | c.1156-2A>T p.X386_splice | Splice Site (SNP) | VAF 33/91 reads (36%) | catalogued as COSV56131370; called by muse, mutect2, varscan2
- FAT4 | c.7T>G p.L3V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as COSV67886986; called by muse, mutect2
- FETUB | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54006017; called by muse, mutect2, varscan2
- GAB3 | c.1736C>T p.T579M | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557246040, COSV65819845; called by muse, mutect2, varscan2
- GABRQ | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100941218; called by muse, mutect2, varscan2
- GATAD1 | c.378C>T p.P126= | Splice Region (SNP) | VAF 31/69 reads (45%) | catalogued as rs1014941169, COSV55319743; called by muse, mutect2, varscan2
- GCLC | c.1606C>G p.L536V (on ENST00000643939; = p.L534V on NM_001498.4) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV57595877; called by muse, mutect2, varscan2
- GDF6 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749537908, COSV54629041; called by muse, mutect2, varscan2
- GDF9 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV51526526; called by muse, mutect2, varscan2
- GDNF | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753300953, COSV58478254; called by muse, mutect2, varscan2
- GNA13 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV71474840; called by muse, mutect2, varscan2
- GPR155 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs575555340, COSV55039498; called by muse, mutect2, varscan2
- GRK3 | c.1088A>T p.Q363L | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60796825; called by muse, mutect2, varscan2
- HNRNPA3 | c.195+2T>A p.X65_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | catalogued as COSV66820869; called by muse, varscan2
- HTR2C | c.973T>C p.C325R | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52214309; called by muse, mutect2, varscan2
- IL7R | c.1094C>A p.S365* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV57406566, COSV57414981; called by muse, varscan2
- IQCH | c.1691T>C p.I564T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60054069; called by mutect2, varscan2
- JPH4 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV58111100; called by muse, mutect2, varscan2
- KHSRP | c.1281G>T p.M427I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.055); catalogued as COSV101231181; called by muse, mutect2, varscan2
- KIF14 | c.3707C>T p.S1236F | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1167880498, COSV100950809; called by muse, mutect2, varscan2
- KIF6 | c.1619G>T p.R540I | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV54680776; called by muse, mutect2, varscan2
- KLHDC8B | c.713T>G p.F238C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100234174; called by muse, mutect2, varscan2
- KRT35 | c.587T>A p.V196E | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99877762; called by muse, mutect2, varscan2
- KRTAP6-2 | c.50G>A p.C17Y | Missense Mutation (SNP) | VAF 165/329 reads (50%) | PolyPhen possibly damaging (0.837); catalogued as COSV58182428; called by muse, mutect2, varscan2
- L3MBTL4 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs761891239, COSV53114527; called by muse, mutect2, varscan2
- LHX8 | c.217T>G p.C73G | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99633626; called by muse, mutect2, varscan2
- MAL | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV100015725; called by muse, mutect2, varscan2
- MDH1B | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs780661298, COSV65590123; called by muse, mutect2, varscan2
- MED6 | c.513T>G p.I171M | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV56450411; called by muse, mutect2, varscan2
- MFSD12 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV62597929; called by muse, mutect2, varscan2
- MRGPRX2 | c.796G>T p.V266F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.05); catalogued as COSV61674313; called by muse, mutect2, varscan2
- MTREX | c.2773A>G p.T925A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs756735220, COSV57926716; called by muse, mutect2, varscan2
- MUC16 | c.11326T>G p.L3776V | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as rs747063101, COSV101199658; called by muse, mutect2, varscan2
- NCAN | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53052518; called by muse, mutect2, varscan2
- NEK3 | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs1444920746, COSV51617479; called by muse, mutect2, varscan2
- NFIB | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66626827, COSV66628240; called by muse, mutect2, varscan2
- NHLH2 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); catalogued as COSV57202309; called by muse, mutect2, varscan2
- NKAPL | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV59197201; called by muse, mutect2, varscan2
- NKTR | c.3643G>C p.E1215Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV51772487; called by muse, mutect2, varscan2
- NR2E3 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1361341993, COSV58909678; called by muse, mutect2, varscan2
- NTM | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66206711; called by muse, mutect2, varscan2
- NTRK1 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100693340, COSV100693386, COSV62326343; called by muse, mutect2, varscan2
- OR10V1 | c.49T>G p.F17V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55698521; called by muse, mutect2
- OR14A16 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100713767; called by muse, mutect2, varscan2
- OR4C12 | c.739T>G p.L247V | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV58859350; called by muse, mutect2
- OR4D6 | c.266G>T p.R89M | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV55659976; called by muse, mutect2, varscan2
- OR51E1 | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.986); catalogued as COSV67810176; called by muse, mutect2, varscan2
- OR52I2 | c.879G>T p.W293C | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV57045285; called by muse, mutect2, varscan2
- OR52M1 | c.544T>A p.C182S | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64172132; called by muse, mutect2
- OR5AN1 | c.59_60insG p.D20Efs*47 | Frame Shift Ins (INS) | VAF 42/204 reads (21%) | catalogued as COSV58322273; called by mutect2, pindel, varscan2
- OR5AR1 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57254110; called by muse, mutect2
- OR5K3 | c.646T>G p.Y216D | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67350191; called by muse, mutect2, varscan2
- OR5M8 | c.752A>C p.Y251S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59117076; called by muse, mutect2, varscan2
- OR5W2 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100747736, COSV60616510; called by muse, mutect2
- PAH | c.644A>T p.K215M | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV61017204; called by muse, mutect2, varscan2
- PAX6 | c.1047C>G p.S349R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53793924; called by muse, mutect2, varscan2
- PCDH17 | c.625C>A p.H209N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100931591, COSV64973089; called by muse, mutect2, varscan2
- PCDH17 | c.3118A>C p.T1040P | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV100931593, COSV100932213; called by muse, mutect2, varscan2
- PCDHGB3 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs762173867, COSV53953480; called by muse, mutect2, varscan2
- PCSK7 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs747236462, COSV58007763; called by muse, mutect2, varscan2
- PDE4B | c.148T>G p.L50V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.899); catalogued as COSV58480420; called by muse, mutect2, varscan2
- PGR | c.2238C>A p.D746E | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199796213, COSV99678234; called by muse, mutect2, varscan2
- PHLDB3 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367616579; called by muse, mutect2, varscan2
- PKHD1L1 | c.9670C>A p.L3224I | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV65740444; called by muse, mutect2, varscan2
- PLAGL2 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV99867168; called by muse, mutect2, varscan2
- PLEC | c.11128G>A p.D3710N (on ENST00000322810 / NM_201380.4; = p.D3600N on NM_000445.5) | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1554677172, COSV59646490; called by muse, mutect2, varscan2
- PLXNA1 | c.177G>C p.Q59H | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.637); catalogued as COSV52527556; called by muse, mutect2, varscan2
- PRAMEF4 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52438249; called by muse, mutect2, varscan2
- PROSER2 | c.48C>G p.D16E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.808); catalogued as COSV53206213; called by muse, mutect2, varscan2
- PRR30 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.178); catalogued as COSV53206549; called by muse, mutect2, varscan2
- PTPN5 | c.8A>G p.Y3C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs369144651, COSV62126564; called by muse, mutect2, varscan2
- RAB6C | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 89/517 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.021); catalogued as COSV101308491; called by muse, mutect2, varscan2
- RNF17 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99693029; called by muse, mutect2, varscan2
- ROBO1 | c.3221C>T p.A1074V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV71395450; called by muse, mutect2, varscan2
- RSPO3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 63/184 reads (34%) | catalogued as rs773759447, COSV63150663; called by muse, mutect2, varscan2
- RTEL1 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs994457956, COSV100542156; called by muse, mutect2
- RYR1 | c.4004G>A p.R1335H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.718); catalogued as rs750256869, COSV62099785; ClinVar: uncertain significance; called by mutect2, varscan2
- RYR2 | c.12417G>C p.M4139I | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV100769801; called by muse, mutect2, varscan2
- SAR1A | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV64699665; called by muse, mutect2, varscan2
- SARDH | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs775453942, COSV64096284; called by muse, mutect2, varscan2
- SBSN | c.1481T>A p.L494H (on ENST00000452271 / NM_001166034.2; = p.L151H on NM_198538.4) | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.383); catalogued as COSV71733282; called by muse, mutect2, varscan2
- SCLY | c.355G>T p.V119L (on ENST00000651534; = p.V111L on NM_016510.7) | Missense Mutation (SNP) | VAF 93/338 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.039); catalogued as COSV54544129, COSV99615609; called by muse, mutect2, varscan2
- SEC61A2 | c.137G>C p.C46S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100036427, COSV53652737; called by muse, mutect2, varscan2
- SELP | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs927440339, COSV55253155; called by muse, mutect2, varscan2
- SERPINA10 | c.373A>C p.K125Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV56228629; called by muse, mutect2, varscan2
- SERTAD3 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs760926284, COSV59325354; called by muse, mutect2, varscan2
- SFMBT2 | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1448090593, COSV62806085; called by muse, mutect2, varscan2
- SH3RF3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV58687402; called by muse, mutect2, varscan2
- SLC26A6 | c.1011C>A p.N337K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV56572627, COSV56575034; called by muse, mutect2, varscan2
- SLC28A3 | c.1534G>T p.G512C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66153550; called by muse, mutect2, varscan2
- SLC5A5 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 91/169 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs911039055, COSV99715007; called by muse, mutect2, varscan2
- SLC9C1 | c.29dup p.S11Qfs*3 | Frame Shift Ins (INS) | VAF 61/150 reads (41%) | catalogued as rs749004401; called by mutect2, varscan2
- SMARCD3 | c.946G>T p.D316Y (on ENST00000262188 / NM_001003801.2; = p.D303Y on NM_003078.4) | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs758051223, COSV99222802; called by muse, mutect2, varscan2
- SP2 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV65064320; called by muse, mutect2, varscan2
- SPATS2L | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs368871834; called by muse, mutect2, varscan2
- STK31 | c.2731T>G p.L911V | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV100669329; called by muse, mutect2
- STUB1 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV99555640; called by muse, mutect2, varscan2
- SYCP1 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 92/291 reads (32%) | catalogued as COSV101051238, COSV65695272; called by muse, mutect2, varscan2
- SYCP1 | c.1305A>C p.E435D | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV65698270; called by muse, varscan2
- SYNE1 | c.24604C>T p.R8202C (on ENST00000367255 / NM_182961.4; = p.R8131C on NM_033071.3) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280986749, COSV99549489; called by muse, mutect2, varscan2
- TAFA5 | c.268A>G p.I90V (on ENST00000402357 / NM_001082967.3; = p.I83V on NM_015381.7) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV100385930; called by muse, mutect2, varscan2
- TARBP1 | c.2073C>A p.C691* | Nonsense Mutation (SNP) | VAF 47/177 reads (27%) | catalogued as COSV50187333; called by muse, mutect2, varscan2
- TCERG1L | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV64051200; called by muse, mutect2, varscan2
- TECRL | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV67087666; called by muse, mutect2, varscan2
- THSD7B | c.2641A>G p.T881A | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99749540; called by muse, mutect2, varscan2
- TK1 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99857199; called by muse, mutect2, varscan2
- TLE1 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV64690669; called by mutect2, varscan2
- TMTC3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376704540, COSV57124321; called by muse, mutect2, varscan2
- TOPORS | c.2489C>T p.S830L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV62117168; called by muse, mutect2, varscan2
- TPST1 | c.424T>A p.L142I | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV59177594; called by muse, mutect2, varscan2
- TRMT13 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as COSV61583176; called by muse, mutect2, varscan2
- TRPV5 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs771239971, COSV54682696; called by muse, mutect2, varscan2
- TSPAN5 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.597); catalogued as COSV59876569; called by muse, mutect2, varscan2
- TTN | c.62993A>T p.K20998M (on ENST00000591111; = p.K13574M on NM_003319.4) | Missense Mutation (SNP) | VAF 35/161 reads (22%) | PolyPhen probably damaging (0.944); catalogued as COSV60117284; called by muse, mutect2, varscan2
- TTN | c.32416G>A p.A10806T (on ENST00000591111; = p.A9879T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/204 reads (26%) | PolyPhen benign (0); catalogued as rs200321239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.14339A>C p.E4780A (on ENST00000591111; = p.E3853A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/168 reads (19%) | PolyPhen probably damaging (0.921); catalogued as COSV60117333; called by muse, mutect2, varscan2
- UGGT2 | c.4030G>C p.E1344Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65072987, COSV65075559; called by muse, mutect2, varscan2
- USP53 | c.2679C>G p.N893K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV56795272; called by muse, mutect2, varscan2
- UTP20 | c.5905G>A p.G1969S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as rs759472914, COSV55378653, COSV55384205; called by muse, mutect2, varscan2
- VEGFC | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as rs1327055032, COSV54601366; called by muse, varscan2
- WARS2 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765994519, COSV52479178; called by muse, mutect2, varscan2
- WFS1 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.725); catalogued as rs1229936850, COSV56989542; called by muse, mutect2, varscan2
- ZACN | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.645); catalogued as COSV58036481; called by muse, mutect2, varscan2
- ZDHHC7 | c.615G>A p.W205* | Nonsense Mutation (SNP) | VAF 50/169 reads (30%) | catalogued as COSV58212849; called by muse, mutect2, varscan2
- ZEB1 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100314268, COSV58043976, COSV58052245; called by muse, mutect2, varscan2
- ZFAT | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs754427782, COSV64739847; called by muse, mutect2, varscan2
- ZNF248 | c.699G>C p.K233N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100627589; called by muse, mutect2, varscan2
- ZNF292 | c.3631A>G p.I1211V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1475176085, COSV60540704; called by muse, mutect2, varscan2
- ZNF329 | c.447C>A p.Y149* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV63772699; called by muse, mutect2, varscan2
- ZNF429 | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV61916642; called by muse, mutect2
- ZNF484 | c.1850T>A p.F617Y | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60258058; called by muse, mutect2, varscan2
- ZNF514 | c.109T>G p.L37V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as COSV54634242; called by muse, mutect2
- ZNF589 | c.43+1G>A p.X15_splice | Splice Site (SNP) | VAF 31/82 reads (38%) | catalogued as COSV61220530; called by muse, mutect2, varscan2
- APC | c.4240del p.V1414* | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- CHFR | c.289_290del p.L97Tfs*14 | Frame Shift Del (DEL) | VAF 45/86 reads (52%) | called by mutect2, pindel, varscan2
- LRRC1 | c.192del p.G65Dfs*14 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.560_561delinsCAG p.Q187Pfs*9 | Frame Shift Ins (INS) | VAF 66/257 reads (26%) | called by pindel, varscan2*
- SHPRH | c.2559_2560del p.G854Ifs*14 | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | called by pindel, varscan2
- SYNE2 | c.19952dup p.S6651Rfs*83 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- TBC1D32 | c.3065del p.F1022Sfs*5 | Frame Shift Del (DEL) | VAF 41/159 reads (26%) | called by mutect2, pindel, varscan2
- ACER3 | c.774G>A p.V258= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as COSV53600152; called by muse, mutect2, varscan2
- ADAD1 | c.1569A>G p.K523= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV56644121; called by muse, mutect2, varscan2
- ADAMTS2 | c.294C>T p.P98= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as rs778807409, COSV51098445; called by muse, mutect2, varscan2
- AFAP1L1 | c.549C>T p.D183= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs754956697, COSV57044287; called by muse, mutect2, varscan2
- AKAP10 | c.1725A>G p.E575= | Silent (SNP) | VAF 82/252 reads (33%) | catalogued as COSV56731499; called by muse, mutect2, varscan2
- ALMS1 | c.5445C>G p.S1815= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV52511909; called by muse, mutect2, varscan2
- ANO5 | c.1851A>T p.I617= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV61086052; called by muse, mutect2, varscan2
- ATP11A | c.3249G>A p.V1083= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV52113860; called by muse, mutect2, varscan2
- BATF2 | c.582C>A p.A194= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV57250117; called by muse, mutect2, varscan2
- BIRC6 | c.6186C>G p.L2062= | Silent (SNP) | VAF 94/273 reads (34%) | catalogued as COSV70200252; called by muse, mutect2, varscan2
- C1GALT1 | c.516G>A p.T172= | Silent (SNP) | VAF 192/267 reads (72%) | catalogued as rs138478625; called by muse, mutect2, varscan2
- C20orf194 | c.2463C>T p.T821= | Silent (SNP) | VAF 68/109 reads (62%) | catalogued as COSV52697172; called by muse, mutect2, varscan2
- C7orf25 | c.1056A>C p.S352= | Silent (SNP) | VAF 39/231 reads (17%) | catalogued as COSV63273805; called by muse, mutect2, varscan2
- CC2D1A | c.993C>A p.T331= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100528439; called by muse, varscan2
- CDT1 | c.1572C>T p.D524= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs760970895, COSV56348648; called by muse, mutect2, varscan2
- CECR2 | c.2349C>T p.Y783= (on ENST00000342247 / NM_001290047.2; = p.Y600= on NM_001290046.1) | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV52837288, COSV99377781; called by muse, mutect2, varscan2
- CSRNP3 | c.1662A>G p.S554= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100085647; called by muse, mutect2
- DCT | c.429C>T p.G143= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs755335828, COSV65468245; called by muse, mutect2, varscan2
- DEFB115 | c.69T>A p.L23= | Silent (SNP) | VAF 43/263 reads (16%) | catalogued as COSV68723185; called by muse, mutect2, varscan2
- DNMT1 | c.957A>G p.E319= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV61580088; called by muse, mutect2, varscan2
- DSEL | c.1458T>G p.T486= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as COSV59491524, COSV59492166; called by muse, mutect2
- DSPP | c.1419C>A p.G473= | Silent (SNP) | VAF 47/109 reads (43%) | catalogued as COSV99217235; called by muse, mutect2, varscan2
- ECH1 | c.498C>T p.A166= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs376376429; called by muse, mutect2, varscan2
- FAHD1 | c.36C>T p.R12= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs781358600, COSV66899974; called by muse, mutect2
- FAT4 | c.3153A>G p.Q1051= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs372689449; ClinVar: likely benign; called by muse, mutect2, varscan2
- FGF6 | c.186C>T p.R62= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs202212518, COSV57403376; called by muse, mutect2, varscan2
- FOXG1 | c.39C>A p.I13= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs1322636276, COSV100486738; called by mutect2, varscan2
- GJA1 | c.969G>A p.A323= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs764435531, COSV56998252; called by muse, mutect2, varscan2
- HIVEP2 | c.5862C>T p.P1954= | Silent (SNP) | VAF 71/201 reads (35%) | catalogued as COSV50017189; called by muse, mutect2, varscan2
- HLA-DOA | c.267C>T p.I89= | Silent (SNP) | VAF 51/106 reads (48%) | catalogued as COSV57713799; called by muse, mutect2, varscan2
- HNRNPH3 | c.54A>G p.V18= | Silent (SNP) | VAF 90/118 reads (76%) | catalogued as COSV56262544; called by muse, mutect2, varscan2
- HNRNPR | c.636C>T p.T212= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as rs200469820, COSV56420067; called by muse, mutect2, varscan2
- IL7 | c.33A>T p.G11= | Silent (SNP) | VAF 126/214 reads (59%) | catalogued as COSV55675368; called by muse, mutect2, varscan2
- KCNS1 | c.546C>T p.D182= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV60260270; called by muse, mutect2, varscan2
- LIG1 | c.717C>G p.V239= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV54392633; called by muse, mutect2, varscan2
- LIG3 | c.1470G>A p.K490= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs999538119, COSV99252520; called by muse, mutect2, varscan2
- MS4A15 | c.210G>A p.E70= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV61960939; called by muse, mutect2, varscan2
- MYH7B | c.3223C>T p.L1075= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV99482720; called by muse, mutect2
- MYT1L | c.2166C>T p.H722= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs1198596415, COSV67722140; called by muse, mutect2, varscan2
- NLE1 | c.1290C>G p.V430= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV50101701; called by muse, mutect2, varscan2
- NOP56 | c.1410G>A p.E470= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV61390304; called by muse, mutect2, varscan2
- OR10G8 | c.9C>T p.N3= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as rs1276314044, COSV70908448; called by muse, mutect2, varscan2
- PTPRZ1 | c.2871T>G p.T957= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV66429410, COSV66438309; called by muse, mutect2, varscan2
- RAD51AP2 | c.2022T>C p.T674= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as COSV67588234; called by muse, mutect2, varscan2
- RIF1 | c.2256C>T p.F752= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs764253293, COSV54618436; called by muse, mutect2, varscan2
- SERPING1 | c.1464C>T p.F488= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1322006876, COSV53542138; called by muse, mutect2, varscan2
- SH3RF2 | c.1485G>A p.V495= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100767735; called by muse, mutect2, varscan2
- SLC24A3 | c.306C>T p.N102= | Silent (SNP) | VAF 117/403 reads (29%) | catalogued as rs748005995, COSV60111186; called by muse, mutect2, varscan2
- SLC7A3 | c.1608C>T p.P536= | Silent (SNP) | VAF 89/115 reads (77%) | catalogued as COSV53227803; called by muse, mutect2, varscan2
- SMR3B | c.171G>T p.G57= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV59228926, COSV59228983; called by muse, mutect2, varscan2
- SPDEF | c.306G>A p.A102= | Silent (SNP) | VAF 51/86 reads (59%) | catalogued as rs748202781, COSV65001061; called by muse, mutect2, varscan2
- STK32B | c.504G>A p.A168= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs374245288; called by muse, mutect2, varscan2
- TEX14 | c.672G>A p.A224= (on ENST00000240361 / NM_001201457.2; = p.A218= on NM_031272.5) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs564729618, COSV99542085; called by mutect2, varscan2
- TMTC2 | c.1410T>G p.T470= | Silent (SNP) | VAF 58/182 reads (32%) | catalogued as COSV58271707; called by muse, mutect2
- TNFSF14 | c.405C>A p.V135= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99838441; called by muse, mutect2, varscan2
- TP53I11 | c.48G>A p.T16= | Silent (SNP) | VAF 52/87 reads (60%) | catalogued as rs148511543; called by muse, mutect2, varscan2
- TPCN2 | c.1311G>T p.L437= | Silent (SNP) | VAF 46/202 reads (23%) | catalogued as COSV53730024; called by muse, mutect2, varscan2
- USP19 | c.3168C>A p.G1056= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV60046473; called by muse, mutect2, varscan2
- ZNF454 | c.1152T>C p.Y384= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV60767888; called by muse, mutect2, varscan2
- ZNF708 | c.699T>C p.F233= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV63607624; called by muse, mutect2, varscan2
- ZNF761 | c.1221G>A p.E407= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV61888600; called by muse, mutect2, varscan2
- ZNF98 | c.367A>C p.R123= | Silent (SNP) | VAF 99/405 reads (24%) | catalogued as rs1279904981, COSV63335342, COSV63340837; called by muse, mutect2, varscan2
- AL590867.2 | n.95G>A | RNA (SNP) | VAF 8/20 reads (40%) | catalogued as rs370015919; called by muse, mutect2, varscan2
- FOLH1B | n.1793_1794insC | RNA (INS) | VAF 98/448 reads (22%) | called by mutect2, pindel, varscan2
- MIR1270 | chr19:20397752 C>A | 3'Flank (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- MIR329-2 | n.63T>G | RNA (SNP) | VAF 29/328 reads (9%) | catalogued as rs1417718813; called by muse, mutect2
- TTN | c.10361-4987C>T | Intron (SNP) | VAF 124/252 reads (49%) | catalogued as rs766013350, COSV60086500; called by muse, varscan2
